Somatic mutation profile of tumor specimen TCGA-44-4112-01A (aliquot TCGA-44-4112-01A-01D-A271-08) from TCGA case TCGA-44-4112, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-44-4112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9c2b011-b8a1-4247-adca-4e9578cc52ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-4112-10A (Blood Derived Normal), aliquot TCGA-44-4112-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4306ab9b-e5b6-44b7-a1d1-0e83703582bb

The open-access MAF lists 458 somatic variants for this specimen: 354 protein-altering or splice-affecting, 94 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 297, Silent 94, Nonsense Mutation 24, Frame Shift Del 15, Splice Site 10, Splice Region 4, 5'Flank 3, Frame Shift Ins 3, RNA 3, Intron 2, 5'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.6688-1G>T p.X2230_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as rs1057520697, COSV54202103, COSV54217068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV52217797; called by muse, mutect2, varscan2
- ABCA13 | c.7558G>T p.D2520Y | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71282907, COSV71294006; called by muse, mutect2, varscan2
- AC011448.1 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as rs546808333, COSV99389193; called by muse, mutect2, varscan2
- AC011448.1 | c.243G>T p.R81= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99389197; called by muse, mutect2, varscan2
- ACSL5 | c.570G>T p.K190N (on ENST00000354273; = p.K246N on NM_016234.3) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287081923, COSV61128656; called by muse, mutect2, varscan2
- ACTN2 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63971584, COSV63972780; called by muse, mutect2, varscan2
- ADAD1 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56641180; called by muse, mutect2, varscan2
- ADAMTS2 | c.1112T>G p.F371C | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51071752; called by muse, mutect2
- ADAMTS6 | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66856415; called by muse, mutect2, varscan2
- ADGRA3 | c.3116G>T p.S1039I | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV51560144; called by muse, mutect2, varscan2
- ADGRG7 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56293359; called by muse, mutect2, varscan2
- AGAP6 | c.706G>T p.G236W (on ENST00000374056 / NM_001365867.1; = p.G259W on NM_001077665.2) | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65017264; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- AK5 | c.1385G>T p.G462V (on ENST00000354567 / NM_174858.3; = p.G436V on NM_012093.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60967087, COSV60971382; called by muse, mutect2, varscan2
- AKAP1 | c.2432G>C p.R811T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61804980; called by muse, mutect2, varscan2
- ALDH1B1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890973; called by muse, mutect2, varscan2
- ALDH1B1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100890974; called by muse, mutect2, varscan2
- ALK | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV66556053; called by muse, mutect2, varscan2
- AMACR | c.914A>T p.H305L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1234892826, COSV56869419; called by muse, mutect2, varscan2
- ANK1 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1363933552, COSV55871780; called by muse, mutect2, varscan2
- ANK1 | c.2918G>T p.S973I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55871794; called by muse, mutect2, varscan2
- ANK1 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | catalogued as COSV55871816; called by muse, mutect2, varscan2
- ANK2 | c.400T>A p.L134I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52144225; called by muse, mutect2, varscan2
- ANK2 | c.4545C>G p.I1515M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as COSV52144247; called by muse, mutect2, varscan2
- ANK3 | c.6874G>T p.G2292C | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55042841, COSV55078532; called by muse, varscan2
- ANKS1A | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64458574; called by muse, mutect2, varscan2
- AOX1 | c.3673C>A p.Q1225K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV53495023; called by muse, mutect2, varscan2
- APBA1 | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55221169; called by muse, mutect2, varscan2
- AQP9 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 51/165 reads (31%) | catalogued as COSV54967309; called by muse, mutect2, varscan2
- ARHGAP32 | c.3925C>T p.P1309S (on ENST00000310343 / NM_001378025.1; = p.P960S on NM_014715.4) | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV59842819; called by muse, mutect2, varscan2
- ARHGAP35 | c.3827G>T p.G1276V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68329066; called by muse, mutect2
- AS3MT | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100185808, COSV54915471; called by muse, mutect2, varscan2
- ASPM | c.4072T>G p.W1358G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257499021, COSV54124019; called by muse, mutect2, varscan2
- ATP1A2 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483366741, COSV63402010, COSV63403080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.4808C>T p.S1603F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV56512554; called by muse, mutect2, varscan2
- C20orf194 | c.3421+1G>T p.X1141_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV52690812; called by muse, mutect2, varscan2
- C2CD6 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV53790790; called by muse, mutect2, varscan2
- CA10 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.2); catalogued as COSV53336161; called by muse, mutect2, varscan2
- CA10 | c.494T>A p.L165Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53336178; called by muse, mutect2, varscan2
- CACNA1E | c.1339A>T p.I447F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV62381249; called by muse, mutect2, varscan2
- CACNA1E | c.3616A>T p.I1206L | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV62381263; called by muse, mutect2, varscan2
- CACNA1H | c.4660G>T p.V1554L | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV61982951; called by muse, mutect2, varscan2
- CACNA2D3 | c.1782G>T p.G594= | Splice Region (SNP) | VAF 4/30 reads (13%) | catalogued as COSV55510827; called by muse, varscan2
- CAPN11 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1169872168, COSV67235973; called by muse, mutect2, varscan2
- CAPRIN2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs755333884, COSV51830095, COSV51833932; called by muse, mutect2, varscan2
- CASR | c.1869C>A p.N623K (on ENST00000490131; = p.N700K on NM_000388.4) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV56133948, COSV56136537; called by muse, mutect2, varscan2
- CCDC171 | c.472A>T p.M158L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52633399, COSV52650746; called by muse, mutect2
- CCDC185 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64820196; called by muse, mutect2, varscan2
- CCDC8 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56772110; called by muse, mutect2, varscan2
- CCT6B | c.1102A>T p.N368Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58487678; called by muse, mutect2, varscan2
- CD163 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV63129105; called by muse, mutect2, varscan2
- CDH6 | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54063505; called by muse, mutect2, varscan2
- CDH7 | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59881102; called by muse, mutect2, varscan2
- CDHR2 | c.2144T>A p.V715E | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56134249; called by muse, mutect2, varscan2
- CEMIP2 | c.4042G>T p.V1348L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV65485416; called by muse, mutect2, varscan2
- CFAP161 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54428277; called by muse, mutect2, varscan2
- CLEC18B | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV100376057; called by mutect2, varscan2
- CMAS | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 15/37 reads (41%) | catalogued as COSV57555910; called by muse, mutect2, varscan2
- CMTR2 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV57602427; called by muse, mutect2, varscan2
- COL11A1 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62171809; called by muse, mutect2, varscan2
- COL14A1 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV52846519; called by muse, mutect2, varscan2
- COL3A1 | c.4021G>T p.G1341C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140646380, COSV58581376; called by muse, mutect2, varscan2
- COL4A2 | c.2426-2A>G p.X809_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV64624414; called by muse, mutect2, varscan2
- CPPED1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55495415, COSV55498088, COSV55498520; called by muse, mutect2, varscan2
- CPT2 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM137681, COSV53758606, COSV53759770; called by muse, mutect2, varscan2
- CPXCR1 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52160884; called by muse, mutect2, varscan2
- CPXM2 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.14); catalogued as COSV53855721; called by muse, mutect2, varscan2
- CRB1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369775002, COSV66328542; called by muse, mutect2, varscan2
- CSMD1 | c.1293G>T p.Q431H (on ENST00000520002; = p.Q430H on NM_033225.6) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV68164438; called by muse, mutect2, varscan2
- CSMD3 | c.3284G>A p.W1095* (on ENST00000297405 / NM_001363185.1; = p.W991* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52093583; called by muse, mutect2, varscan2
- CTNNB1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV62688598; called by muse, mutect2, varscan2
- CTPS1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.665); catalogued as COSV65451680; called by muse, mutect2, varscan2
- CUX1 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52890038, COSV99469960; called by muse, mutect2, varscan2
- DCC | c.2690C>A p.S897* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV59081983; called by muse, mutect2, varscan2
- DLAT | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.055); catalogued as COSV54768882; called by muse, mutect2, varscan2
- DLGAP2 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70093565, COSV70097468; called by muse, mutect2, varscan2
- DOCK2 | c.4615G>T p.V1539F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56939806; called by muse, mutect2, varscan2
- DOCK2 | c.5290C>A p.L1764M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.523); catalogued as COSV56939815; called by muse, mutect2
- DOP1B | c.6628C>G p.L2210V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV67690556; called by muse, mutect2, varscan2
- DPP6 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.289); catalogued as COSV68052000; called by muse, varscan2
- EEF2K | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53778235; called by muse, mutect2, varscan2
- ELSPBP1 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60412718; called by muse, mutect2, varscan2
- EML2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99840282; called by muse, mutect2, varscan2
- EPC1 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53922877; called by muse, mutect2, varscan2
- EPHX1 | c.67A>C p.K23Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV55298454; called by muse, mutect2, varscan2
- ERBB4 | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53498805, COSV53582580; called by muse, mutect2, varscan2
- ERLEC1 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1163332248, COSV51750457; called by muse, mutect2, varscan2
- ESPNL | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs749808035, COSV58031919; called by muse, mutect2, varscan2
- ESRP2 | c.1577C>T p.T526I (on ENST00000565858 / NM_001365264.1; = p.T516I on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV52171802; called by muse, mutect2, varscan2
- F5 | c.1514A>T p.Y505F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63120088; called by muse, mutect2, varscan2
- FAT1 | c.8788G>T p.D2930Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71671704; called by muse, mutect2, varscan2
- FAT4 | c.6986G>C p.R2329P | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV58670368; called by muse, mutect2, varscan2
- FBXO16 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100672014, COSV60774370; called by muse, mutect2, varscan2
- FCHO2 | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV59269481; called by muse, mutect2
- FCRL5 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 126/222 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.072); catalogued as COSV62511063; called by muse, mutect2, varscan2
- FER | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as COSV55282013; called by muse, mutect2, varscan2
- FEV | c.290A>T p.N97I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55386167; called by muse, mutect2, varscan2
- FILIP1L | c.2792C>G p.T931R (on ENST00000354552 / NM_182909.3; = p.T691R on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202241125, COSV58764433; called by muse, mutect2, varscan2
- FPR2 | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60671776, COSV60674112; called by muse, mutect2, varscan2
- FRAS1 | c.8471A>G p.H2824R | Missense Mutation (SNP) | VAF 124/324 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.443); catalogued as COSV53586785; called by muse, mutect2, varscan2
- FREM1 | c.2861T>A p.V954D | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66517146; called by muse, mutect2, varscan2
- FRMD7 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.52); catalogued as COSV53744471; called by muse, mutect2, varscan2
- FSCB | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV61216383; called by muse, mutect2, varscan2
- FUT1 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59567282, COSV59568535; called by muse, mutect2, varscan2
- GABRA5 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59475374; called by muse, mutect2
- GALR1 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100232022; called by muse, mutect2, varscan2
- GALR1 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100231890, COSV100232024; called by muse, mutect2, varscan2
- GASK1B | c.1156G>C p.G386R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56704263; called by muse, mutect2, varscan2
- GATM | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV67540091; called by mutect2, varscan2
- GCSAML | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63576937; called by muse, mutect2, varscan2
- GLI3 | c.2944G>T p.G982W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67884756; called by muse, varscan2
- GP5 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as rs763048450, COSV59877562; called by muse, varscan2
- GPAT3 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV52355087; called by muse, mutect2, varscan2
- GPATCH1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV50111065; called by muse, mutect2, varscan2
- GPHN | c.1468G>T p.V490F (on ENST00000315266 / NM_001377519.1; = p.V523F on NM_020806.5) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV59472239; called by muse, mutect2, varscan2
- GPM6A | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.376); catalogued as COSV54531166; called by muse, mutect2, varscan2
- GPRIN1 | c.171del p.R58Gfs*78 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | catalogued as rs765009644; called by mutect2, pindel, varscan2
- GPX7 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as COSV63652350, COSV63652897; called by muse, mutect2, varscan2
- GRK5 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64865462; called by muse, mutect2, varscan2
- GRM1 | c.2569C>A p.R857S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51108030; called by muse, mutect2, varscan2
- GRSF1 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54654393, COSV54656122; called by muse, mutect2, varscan2
- GUCY1A1 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.173); catalogued as COSV56648763; called by muse, mutect2, varscan2
- HDAC5 | c.1322A>T p.H441L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV56817011; called by muse, mutect2, varscan2
- HECW1 | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV67820928, COSV67826745; called by muse, mutect2, varscan2
- HGF | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.65); PolyPhen benign (0.052); catalogued as COSV55944972; called by muse, mutect2, varscan2
- HIPK2 | c.2375G>T p.R792L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV61225310; called by muse, mutect2, varscan2
- HNF4A | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1413804456, COSV57379142; called by muse, mutect2
- HPCAL4 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65716021; called by muse, mutect2, varscan2
- HR | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs185501052, COSV57190474; called by muse, mutect2, varscan2
- HTR5A | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55280216; called by muse, mutect2, varscan2
- ICE1 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV56818529; called by muse, mutect2, varscan2
- IFNA1 | c.207C>G p.N69K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.051); catalogued as COSV99439935; called by muse, mutect2, varscan2
- IL4R | c.1361A>T p.K454M | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV50138118; called by muse, mutect2, varscan2
- INSC | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV65408583; called by muse, mutect2, varscan2
- IRAK3 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV54159106; called by muse, mutect2, varscan2
- ITGBL1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101084534, COSV65934807; called by muse, mutect2, varscan2
- IVL | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1271584586, COSV64215377, COSV64217243; called by muse, mutect2, varscan2
- JADE2 | c.1438A>G p.R480G | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50911504; called by muse, mutect2, varscan2
- JCAD | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 51/178 reads (29%) | catalogued as COSV64757763; called by muse, mutect2, varscan2
- KCNA1 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as COSV66836423, COSV66837186; called by muse, mutect2, varscan2
- KCNA4 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.04); catalogued as rs769344328, COSV60250408; called by muse, mutect2, varscan2
- KCNA4 | c.110G>T p.R37M | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60250423; called by muse, mutect2, varscan2
- KCNU1 | c.1178C>G p.S393C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67752745; called by muse, mutect2, varscan2
- KCNU1 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV67752751; called by muse, mutect2, varscan2
- KDM5B | c.4273G>C p.E1425Q | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV52503653; called by muse, mutect2, varscan2
- KDR | c.2817+1G>T p.X939_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV55757409; called by muse, mutect2, varscan2
- KIF17 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56115447; called by muse, mutect2, varscan2
- KIF21A | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | catalogued as COSV62766681; called by muse, mutect2, varscan2
- KNTC1 | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV61078696; called by muse, mutect2, varscan2
- KRT3 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV58814429; called by muse, mutect2, varscan2
- KRT75 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs943299335, COSV52870832; called by muse, mutect2, varscan2
- KRTCAP3 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV51992955; called by muse, mutect2, varscan2
- L1CAM | c.2836G>T p.G946C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62826650, COSV62829026; called by muse, mutect2, varscan2
- L1TD1 | c.1164T>A p.D388E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535166958, COSV63133035; called by muse, mutect2, varscan2
- LAMA1 | c.3046T>A p.C1016S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67531457; called by muse, mutect2, varscan2
- LRFN3 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.065); catalogued as rs1177593086, COSV55816811; called by muse, mutect2, varscan2
- LRFN5 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53241442; called by muse, mutect2, varscan2
- LRP1B | c.3451C>A p.L1151M | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67183201; called by muse, mutect2, varscan2
- LRRC32 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52631315; called by muse, mutect2, varscan2
- LRRC4 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1470797815, COSV50813162; called by muse, mutect2, varscan2
- LRRC49 | c.1594G>C p.V532L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53007549, COSV53010607; called by muse, mutect2
- LRRTM3 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV63660432, COSV63671905; called by muse, mutect2, varscan2
- LSP1 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV61132049; called by muse, mutect2, varscan2
- LVRN | c.2037G>T p.K679N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV63495787; called by muse, mutect2
- MAF1 | c.83G>T p.R28M | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59362541; called by muse, mutect2, varscan2
- MAGEA10 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV54882635; called by muse, mutect2, varscan2
- MAT1A | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV64744529; called by muse, mutect2, varscan2
- MBTPS1 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.26); catalogued as COSV58569172; called by muse, mutect2, varscan2
- MED23 | c.781-1G>T p.X261_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV63429901; called by muse, mutect2, varscan2
- MIDN | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV56293871; called by muse, mutect2, varscan2
- MIS18BP1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV60368875; called by muse, mutect2, varscan2
- MKS1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs774076532, COSV58302494; called by muse, mutect2, varscan2
- MMP3 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV55404934, COSV55407467; called by muse, mutect2, varscan2
- MPPED2 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs763721239, COSV63895845; called by muse, mutect2, varscan2
- MPPED2 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63895850; called by muse, mutect2, varscan2
- MSRB2 | c.511A>C p.N171H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64737083; called by muse, mutect2, varscan2
- MUC16 | c.21541A>T p.T7181S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV67442314; called by muse, mutect2, varscan2
- MUC17 | c.3235G>A p.A1079T | Missense Mutation (SNP) | VAF 292/648 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761787989, COSV60279249; called by muse, mutect2, varscan2
- MYH1 | c.5599A>T p.R1867W | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56843202, COSV99875372; called by muse, mutect2, varscan2
- MYO15A | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1270359345, COSV52751300; called by muse, mutect2, varscan2
- MYO18A | c.1451del p.A484Gfs*3 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as COSV62866958; called by mutect2, varscan2
- NALCN | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV51915483; called by muse, mutect2, varscan2
- NELL1 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV54236125, COSV54257333; called by muse, mutect2, varscan2
- NLRP12 | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.334); catalogued as COSV60743237; called by muse, mutect2, varscan2
- NLRP3 | c.2738C>A p.T913K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV60219292, COSV60225201; called by muse, mutect2, varscan2
- NLRP8 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.89); catalogued as rs1184872960, COSV52582913, COSV52583382; called by muse, mutect2, varscan2
- NME3 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs369561097; called by muse, varscan2
- NOP2 | c.1006G>T p.D336Y (on ENST00000322166 / NM_001258308.2; = p.D332Y on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59109227; called by muse, mutect2
- NOS1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV57606145; called by muse, mutect2
- NPAP1 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV61504018, COSV61512136; called by muse, mutect2, varscan2
- NPFFR2 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100440385, COSV58145977, COSV58149773; called by muse, mutect2, varscan2
- NPSR1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as COSV62195957; called by muse, mutect2, varscan2
- NRG1 | c.215C>A p.A72E (on ENST00000523534; = p.A219E on NM_013962.2) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs754569262, COSV101585021; called by muse, varscan2
- NRXN3 | c.1990_1991insA p.R664Qfs*26 (on ENST00000335750 / NM_001330195.2; = p.R291Qfs*26 on NM_004796.6) | Frame Shift Ins (INS) | VAF 21/84 reads (25%) | catalogued as COSV100206783; called by mutect2, pindel, varscan2
- NSG2 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV57456585; called by muse, mutect2, varscan2
- NSG2 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57456594; called by muse, mutect2, varscan2
- NTRK3 | c.1955G>T p.G652V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV62294707, COSV62313063; called by muse, mutect2, varscan2
- NUDT16 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.316); catalogued as rs1378522401, COSV63248103; called by muse, mutect2, varscan2
- NUF2 | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV54841880; called by muse, mutect2
- NUP155 | c.1229G>T p.R410I (on ENST00000231498 / NM_153485.3; = p.R351I on NM_004298.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51526392; called by muse, mutect2, varscan2
- NUTM1 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV60995007; called by muse, mutect2, varscan2
- OR10W1 | c.654G>C p.K218N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR11H6 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100209809, COSV59643653; called by muse, mutect2, varscan2
- OR2B11 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59509177; called by muse, mutect2, varscan2
- OR4C46 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV60218219; called by muse, mutect2
- OR51F2 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438108, COSV59063609; called by muse, mutect2, varscan2
- OR52B4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281579, COSV68768544; called by muse, mutect2
- OR5F1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53545078; called by muse, mutect2, varscan2
- OR5M10 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV73242231; called by muse, varscan2
- OR5M8 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59115630; called by muse, mutect2, varscan2
- OR6C74 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV59605663; called by muse, mutect2, varscan2
- OR6X1 | c.896T>C p.L299S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV60009268; called by muse, mutect2, varscan2
- OR9Q1 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59035989; called by muse, mutect2, varscan2
- OVCH1 | c.2960T>A p.L987Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58959132; called by muse, mutect2, varscan2
- OVCH2 | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71952628; called by muse, mutect2, varscan2
- OXT | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV54131670; called by muse, varscan2
- PANK2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV57252803, COSV57255074, COSV57255472; called by muse, mutect2
- PAPPA2 | c.2237A>T p.K746I | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62772303; called by muse, mutect2, varscan2
- PAPPA2 | c.4149G>T p.Q1383H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62790051; called by muse, mutect2, varscan2
- PAPPA2 | c.4238G>T p.G1413V | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV62790056; called by muse, mutect2, varscan2
- PCDHA3 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV63538645; called by muse, mutect2, varscan2
- PCDHB8 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50753597; called by muse, mutect2, varscan2
- PCDHGB7 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 52/94 reads (55%) | catalogued as COSV53894124, COSV53920192; called by muse, mutect2, varscan2
- PCF11 | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV53527045; called by muse, mutect2, varscan2
- PCNX1 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53088744; called by muse, mutect2
- PDE1C | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV68803371, COSV68812355; called by muse, mutect2, varscan2
- PDGFRA | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV57264359; called by muse, mutect2, varscan2
- PIK3C2G | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV56795719; called by muse, mutect2, varscan2
- PIWIL2 | c.2360G>C p.S787T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV63249511, COSV63252170; called by muse, mutect2, varscan2
- PLCB1 | c.3650G>C p.*1217Sext*38 | Nonstop Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV62036601, COSV62040931; called by muse, mutect2, varscan2
- PLCL1 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70820641; called by muse, mutect2, varscan2
- PLEC | c.6438G>T p.E2146D (on ENST00000322810 / NM_201380.4; = p.E2036D on NM_000445.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as COSV59601124, COSV59601814; called by muse, mutect2
- PLK4 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54636158; called by muse, mutect2
- PLPPR3 | c.786C>A p.D262E (on ENST00000520876 / NM_001270366.2; = p.D290E on NM_024888.2) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV62458546; called by muse, mutect2, varscan2
- PLPPR4 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV64564152; called by muse, mutect2, varscan2
- PNLDC1 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV51703622, COSV51707507; called by muse, mutect2, varscan2
- PPP5C | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV50139139; called by muse, mutect2, varscan2
- PRLR | c.360C>G p.D120E | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV51492857, COSV51496691; called by muse, mutect2, varscan2
- PRSS1 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs1224059005, COSV61190144; called by muse, mutect2, varscan2
- PSD2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs201057651; called by muse, mutect2, varscan2
- PTBP2 | c.1465A>T p.T489S (on ENST00000426398 / NM_001300986.2; = p.T481S on NM_021190.4) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as COSV64623148; called by muse, mutect2, varscan2
- PTPRH | c.3137T>A p.L1046H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54742298; called by muse, mutect2, varscan2
- PTPRN2 | c.380+2T>G p.X127_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV67020503; called by muse, mutect2, varscan2
- RASA3 | c.1986C>G p.C662W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863203, COSV61864398; called by muse, mutect2, varscan2
- RASGRF2 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.632); catalogued as rs376863152; called by muse, mutect2, varscan2
- RBAK | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs758338137, COSV62330717; called by muse, mutect2, varscan2
- RBM10 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV61311108; called by muse, mutect2, varscan2
- RELN | c.9127C>A p.L3043M | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs747144808, COSV58984231; called by muse, mutect2, varscan2
- RGS22 | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV62656914; called by muse, mutect2
- RHOBTB2 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52569561; called by muse, mutect2, varscan2
- RIC1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52604540; called by muse, mutect2, varscan2
- RNF20 | c.2307G>T p.K769N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66660334; called by muse, mutect2, varscan2
- ROBO2 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165056, COSV59894479; called by muse, mutect2, varscan2
- RPL3L | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51905073; called by muse, mutect2, varscan2
- RYR1 | c.1054T>G p.S352A | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV62087808; called by muse, mutect2, varscan2
- SCNN1D | c.289G>A p.V97I (on ENST00000338555; = p.V261I on NM_001130413.4) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV57639608; called by muse, mutect2
- SCRIB | c.3164G>T p.G1055V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57581864; called by muse, mutect2, varscan2
- SENP2 | c.1558A>T p.R520* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV56192291; called by muse, mutect2, varscan2
- SEPTIN14 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66425925; called by muse, mutect2, varscan2
- SERPINA9 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54072536; called by muse, mutect2, varscan2
- SGIP1 | c.1500A>T p.L500F | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52762254; called by muse, mutect2, varscan2
- SHANK1 | c.5555C>A p.P1852H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV53242208; called by muse, mutect2, varscan2
- SI | c.3766C>G p.Q1256E | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1286260158, COSV100013884, COSV100015767, COSV52264857; called by muse, mutect2
- SIGLEC10 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774331697, COSV59478519; called by muse, mutect2, varscan2
- SIGLECL1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV57061914; called by muse, mutect2, varscan2
- SIPA1L1 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.462); catalogued as COSV62168225; called by muse, mutect2, varscan2
- SIT1 | c.324C>A p.D108E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52399549; called by muse, mutect2, varscan2
- SKAP1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as rs142272724; called by muse, mutect2, varscan2
- SLC12A2 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52467592; called by muse, mutect2
- SLC1A3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54313836; called by muse, mutect2, varscan2
- SLC24A3 | c.1476C>A p.Y492* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV60110635; called by muse, mutect2, varscan2
- SLC7A14 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV51577519, COSV51586829; called by muse, mutect2, varscan2
- SLFN11 | c.1198+1G>T p.X400_splice | Splice Site (SNP) | VAF 22/62 reads (35%) | catalogued as COSV57697288; called by muse, mutect2, varscan2
- SLIT3 | c.4375C>A p.R1459S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.22); catalogued as COSV100265856, COSV60591033; called by muse, varscan2
- SMARCC1 | c.2669G>C p.R890T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54376746; called by muse, mutect2, varscan2
- SPAG17 | c.4966C>T p.R1656* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs371789370, COSV60452343; called by muse, mutect2
- SPATA31A1 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as rs1287738537; called by mutect2, varscan2
- SRRM2 | c.7733+1G>T p.X2578_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV51939709; called by muse, mutect2, varscan2
- STAT1 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV63114958, COSV63116930; called by muse, mutect2, varscan2
- STXBP5 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51647463; called by muse, mutect2
- STXBP5L | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56498612; called by muse, mutect2, varscan2
- SUSD1 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV62582079; called by muse, mutect2, varscan2
- SYT1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV54031521; called by muse, mutect2, varscan2
- SYT11 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 25/591 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540504685, COSV64173622; called by muse, mutect2
- TARS2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64694423; called by muse, mutect2, varscan2
- TBC1D5 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV53748333; called by muse, mutect2
- TCF12 | c.31A>T p.I11L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs777290901, COSV51003244; called by mutect2, varscan2
- TENM1 | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as COSV64424333; called by muse, mutect2, varscan2
- TENM3 | c.2669C>A p.P890Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV69298593, COSV69309771; called by muse, mutect2, varscan2
- TENM3 | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1190612157, COSV69298602; called by muse, mutect2, varscan2
- TFPI2 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55989790, COSV99746512; called by muse, mutect2, varscan2
- THBS4 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV63467600; called by muse, mutect2, varscan2
- THEMIS | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs756380182, COSV64069004; called by muse, mutect2, varscan2
- TKTL2 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV54917269; called by muse, mutect2, varscan2
- TLN1 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59203718; called by muse, mutect2, varscan2
- TLX3 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99740738; called by muse, mutect2, varscan2
- TNR | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV54868322; called by muse, mutect2, varscan2
- TRAPPC12 | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60844873; called by muse, mutect2, varscan2
- TRPA1 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51555066, COSV51570039; called by muse, mutect2, varscan2
- TRPM3 | c.1006G>T p.A336S (on ENST00000357533 / NM_001366142.2; = p.A181S on NM_020952.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1429313690, COSV62467143; called by muse, mutect2
- TRPS1 | c.2664G>A p.R888= (on ENST00000220888 / NM_001330599.2; = p.R901= on NM_014112.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 23/87 reads (26%) | catalogued as COSV55224758; called by muse, mutect2, varscan2
- TSC2 | c.1546del p.A516Qfs*19 | Frame Shift Del (DEL) | VAF 51/155 reads (33%) | catalogued as rs397515272; ClinVar: not provided; called by mutect2, pindel, varscan2
- TSPAN32 | c.718C>A p.R240= | Splice Region (SNP) | VAF 9/59 reads (15%) | catalogued as rs751947184, COSV51718538, COSV51722084; called by muse, mutect2
- TTN | c.98222T>C p.F32741S (on ENST00000591111; = p.F25317S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | PolyPhen probably damaging (0.961); catalogued as COSV59869790; called by muse, mutect2, varscan2
- TTN | c.9854G>T p.C3285F (on ENST00000591111; = p.C3239F on NM_003319.4) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | PolyPhen possibly damaging (0.748); catalogued as COSV59869820; called by muse, mutect2, varscan2
- UBA6 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59173812; called by muse, mutect2, varscan2
- UBE2O | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as COSV60059573; called by muse, mutect2, varscan2
- UBE3B | c.833T>C p.L278S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55090688; called by muse, mutect2, varscan2
- UGT2B15 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV57732776; called by muse, mutect2, varscan2
- UNC5D | c.1922A>C p.Q641P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV54766919; called by muse, mutect2, varscan2
- UPP2 | c.715T>A p.L239I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV50046260; called by muse, mutect2, varscan2
- USH2A | c.1603A>G p.R535G | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV56323482; called by muse, mutect2
- USP28 | c.987T>A p.C329* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV50155526; called by muse, mutect2, varscan2
- USP29 | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as COSV54139610; called by muse, mutect2, varscan2
- USP31 | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54848952; called by muse, mutect2, varscan2
- VCAM1 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54117600; called by muse, mutect2, varscan2
- VGLL3 | c.921C>G p.S307R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67352340; called by muse, mutect2, varscan2
- WNT1 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV53295154; called by muse, mutect2, varscan2
- XIRP2 | c.1264G>T p.G422C (on ENST00000628543; = p.G597C on NM_152381.6) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV54680622, COSV54682372; called by muse, mutect2, varscan2
- YBX2 | c.821del p.P274Rfs*126 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as COSV99142775; called by mutect2, pindel, varscan2
- ZBTB47 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51763435; called by muse, mutect2, varscan2
- ZFAND1 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV55106502; called by muse, mutect2, varscan2
- ZFHX4 | c.7126G>C p.A2376P | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV50480035, COSV50509053, COSV51442130; called by muse, mutect2, varscan2
- ZFP41 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV58085992, COSV58086935; called by muse, mutect2, varscan2
- ZNF114 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59943482; called by muse, mutect2, varscan2
- ZNF23 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV61840437; called by muse, mutect2, varscan2
- ZNF264 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV54040517; called by muse, mutect2, varscan2
- ZNF335 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763158895, COSV59815833; called by muse, mutect2, varscan2
- ZNF516 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1261693552, COSV71586638; called by muse, mutect2, varscan2
- ZNF780B | c.1384C>G p.Q462E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs776575039, COSV55461555, COSV55466028; called by muse, mutect2, varscan2
- ZNF835 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV73379142; called by muse, mutect2, varscan2
- ZZZ3 | c.1686G>T p.L562F | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66231086; called by muse, mutect2, varscan2
- ADRA2A | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ASTN1 | c.1651del p.V551* | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- CMTR1 | c.1447del p.L483Wfs*3 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | called by pindel, varscan2
- FRMPD2 | c.2950C>A p.P984T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HS6ST1 | c.754_755delinsT p.R252Sfs*6 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2*
- IGHV3OR16-8 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- IGKV3D-20 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGLV1-36 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.367A>T p.I123F (on ENST00000396284; = p.I84F on NM_001080770.2) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, varscan2
- LHX8 | c.18+1del | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- MYH8 | c.3475del p.A1159Qfs*8 | Frame Shift Del (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- NONO | c.570del p.G191Afs*25 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- OR4C16 | c.116del p.G39Vfs*4 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | called by mutect2, pindel
- OR5R1 | c.465del p.A156Pfs*11 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.2620_2623delinsTCCTT p.P874Sfs*138 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | called by pindel, varscan2*
- PPP2R5E | c.156del p.D53Tfs*12 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- TAF2 | c.2432_2462del p.S811Tfs*2 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel
- TPTE | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRBV3-1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- UGT3A1 | c.188dup p.L63Ffs*6 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- ZNF423 | c.805del p.D269Tfs*107 (on ENST00000563137 / NM_001379286.1; = p.D261Tfs*107 on NM_015069.4) | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13584A>T p.T4528= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1309384422, COSV68942920; called by muse, mutect2, varscan2
- ABCC5 | c.3105G>T p.L1035= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV55586782, COSV55596668; called by muse, mutect2, varscan2
- ADAM18 | c.2112C>A p.T704= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV55843337; called by muse, mutect2, varscan2
- ADORA1 | c.573C>T p.P191= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV55141148; called by muse, mutect2, varscan2
- AHSG | c.492G>C p.A164= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV56606921, COSV56607726; called by muse, mutect2, varscan2
- ATAD3C | c.1122G>C p.L374= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58019027; called by muse, mutect2, varscan2
- BAIAP3 | c.2349G>T p.L783= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV50103499; called by muse, mutect2, varscan2
- BBS10 | c.1743G>C p.P581= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV67913016; called by muse, mutect2, varscan2
- BMP10 | c.237G>T p.V79= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV54893878; called by muse, mutect2, varscan2
- CA11 | c.937C>A p.R313= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV50032701, COSV99320762; called by muse, mutect2, varscan2
- CACNG7 | c.654C>T p.R218= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV55812860; called by muse, mutect2, varscan2
- CAMSAP1 | c.2706G>T p.L902= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV56718065; called by muse, mutect2, varscan2
- CDKL1 | c.774T>C p.S258= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV53577662; called by muse, mutect2, varscan2
- CHD4 | c.1275G>T p.G425= (on ENST00000357008 / NM_001363606.2; = p.G438= on NM_001273.5) | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as COSV58894410; called by muse, mutect2, varscan2
- CHD6 | c.7050G>A p.E2350= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV64688084; called by muse, mutect2
- CHST4 | c.972C>A p.A324= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV58296392; called by muse, mutect2, varscan2
- CLCA4 | c.66C>A p.S22= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs753110300, COSV55365840; called by muse, mutect2, varscan2
- CNTNAP2 | c.3183C>G p.P1061= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV62141356; called by muse, mutect2, varscan2
- COL26A1 | c.516T>G p.T172= (on ENST00000313669 / NM_001278563.3; = p.T170= on NM_133457.4) | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV58119582; called by muse, mutect2, varscan2
- CSMD3 | c.5490C>A p.S1830= (on ENST00000297405 / NM_001363185.1; = p.S1726= on NM_052900.3) | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV52093564, COSV52297977; called by muse, mutect2, varscan2
- CYP4F11 | c.1236C>A p.R412= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV56125462, COSV56130652; called by muse, mutect2, varscan2
- DDX58 | c.1204C>T p.L402= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV65881971; called by muse, mutect2, varscan2
- DTX4 | c.495A>T p.T165= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV57088091; called by muse, mutect2, varscan2
- EPHA3 | c.1101G>T p.G367= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV60692856; called by muse, mutect2, varscan2
- FASTKD5 | c.1665A>T p.S555= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53904023; called by muse, mutect2, varscan2
- FHL5 | c.300C>T p.S100= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV58734999, COSV58735731; called by muse, mutect2, varscan2
- FLNA | c.3822C>G p.A1274= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV61036639; called by muse, mutect2, varscan2
- FMNL1 | c.2100C>A p.A700= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV58954930; called by muse, mutect2, varscan2
- FOXI1 | c.159C>G p.G53= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV60387884; called by muse, mutect2, varscan2
- FSCB | c.2040T>A p.A680= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61216378; called by muse, varscan2
- GAREM1 | c.1230G>T p.G410= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV52505384; called by muse, mutect2, varscan2
- GID8 | c.612C>T p.N204= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1331167089, COSV56610887; called by muse, mutect2, varscan2
- HERC1 | c.327A>T p.V109= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV71245810; called by muse, mutect2, varscan2
- HIVEP2 | c.5835C>T p.S1945= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV50005337; called by muse, mutect2, varscan2
- HMMR | c.1401C>T p.A467= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV62373635; called by muse, mutect2, varscan2
- HPS5 | c.3372C>G p.L1124= (on ENST00000349215 / NM_181507.2; = p.L1010= on NM_007216.4) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV61686989; called by muse, mutect2, varscan2
- HR | c.3039G>C p.L1013= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1450165382, COSV57190462; called by muse, mutect2, varscan2
- IL1RL1 | c.1110T>A p.T370= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV52111835, COSV99293582; called by muse, mutect2, varscan2
- ITCH | c.1845A>T p.A615= (on ENST00000262650 / NM_001257137.3; = p.A574= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV52929023; called by muse, mutect2, varscan2
- ITGA1 | c.1962G>T p.G654= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as COSV50876315; called by muse, mutect2, varscan2
- KIR3DL2 | c.849C>G p.G283= | Silent (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- LAMA2 | c.4239C>G p.T1413= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs770520233, COSV70337364; called by muse, mutect2, varscan2
- LILRA1 | c.951G>C p.L317= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV52177505, COSV52179591; called by muse, mutect2, varscan2
- MMP26 | c.348G>A p.K116= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV56171182; called by muse, mutect2, varscan2
- MON2 | c.1837C>T p.L613= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV54802542, COSV54812447; called by muse, mutect2, varscan2
- MTUS2 | c.3570G>C p.L1190= (on ENST00000612955 / NM_001366650.1; = p.L169= on NM_015233.6) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs752413944, COSV60157757; called by muse, mutect2, varscan2
- MUC16 | c.15570T>C p.P5190= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV67442327; called by muse, mutect2, varscan2
- NDUFS1 | c.1335G>T p.L445= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV51907657; called by muse, mutect2
- NEFH | c.2724G>A p.K908= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV60214718; called by muse, mutect2, varscan2
- NMS | c.252T>A p.V84= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV65258252; called by muse, mutect2
- OCA2 | c.1299G>T p.A433= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV62337620; called by muse, mutect2, varscan2
- OR13C4 | c.690G>A p.S230= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs146391633; called by muse, mutect2, varscan2
- OR2W1 | c.861G>T p.P287= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV65851356; called by muse, mutect2, varscan2
- OR8B4 | c.495G>T p.L165= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV62069114; called by muse, mutect2, varscan2
- OR8J1 | c.786C>A p.P262= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV57316416; called by muse, mutect2, varscan2
- PCDHB12 | c.1878C>A p.T626= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as COSV99506886, COSV99507591; called by muse, mutect2, varscan2
- PCDHGA12 | c.1884G>T p.T628= | Silent (SNP) | VAF 30/218 reads (14%) | catalogued as COSV52742428, COSV52755079; called by muse, varscan2
- PCDHGB1 | c.1269G>A p.K423= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV53894110; called by muse, mutect2, varscan2
- PGLYRP4 | c.1035G>T p.L345= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as COSV62834482; called by muse, mutect2, varscan2
- PLA2G5 | c.279C>A p.G93= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100908204, COSV64282754; called by muse, mutect2
- PROSER2 | c.363G>A p.E121= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV53203945; called by muse, mutect2, varscan2
- PTGS1 | c.810G>T p.V270= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56289969; called by muse, mutect2, varscan2
- PZP | c.1785T>A p.A595= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV54353853; called by muse, mutect2, varscan2
- RP1L1 | c.3462G>T p.S1154= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV66751418; called by muse, mutect2, varscan2
- RSRC2 | c.1215T>C p.A405= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100063735; called by muse, mutect2, varscan2
- RTN1 | c.2037G>T p.L679= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV50718490; called by muse, mutect2, varscan2
- RUNX3 | c.21C>T p.F7= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs746716793, COSV58845364; called by muse, mutect2, varscan2
- RXFP3 | c.241C>A p.R81= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs780429160, COSV57503789, COSV57503902; called by muse, mutect2, varscan2
- SARAF | c.750T>C p.F250= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV56356787; called by muse, mutect2, varscan2
- SCUBE3 | c.2349A>G p.P783= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV51454638; called by muse, mutect2, varscan2
- SDK2 | c.2701C>T p.L901= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV66180838; called by muse, mutect2, varscan2
- SHPRH | c.3258A>T p.I1086= (on ENST00000275233 / NM_001042683.3; = p.I1095= on NM_173082.3) | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV51604365; called by muse, mutect2
- SIDT2 | c.1113T>A p.G371= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV54054840; called by muse, mutect2, varscan2
- SLAMF1 | c.588C>A p.L196= | Silent (SNP) | VAF 74/120 reads (62%) | catalogued as COSV52497430; called by muse, mutect2, varscan2
- SLC14A2 | c.756C>T p.G252= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV54905847; called by muse, mutect2, varscan2
- SLC35G5 | c.276C>T p.D92= | Silent (SNP) | VAF 68/326 reads (21%) | catalogued as COSV55310242; called by muse, varscan2
- SLC9A3 | c.1245C>T p.R415= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs143761751, COSV99375879; called by muse, mutect2, varscan2
- SPATA31A3 | c.301C>T p.L101= | Silent (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- TAAR2 | c.537C>A p.V179= (on ENST00000367931 / NM_001033080.1; = p.V134= on NM_014626.3) | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV51578350; called by muse, mutect2, varscan2
- TGIF2LX | c.24G>T p.P8= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1216899464, COSV52213098, COSV52213469; called by muse, mutect2, varscan2
- THUMPD1 | c.1014A>T p.A338= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV67262943; called by muse, mutect2, varscan2
- TMC2 | c.2130G>A p.V710= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV62649442; called by muse, mutect2, varscan2
- TMEM200A | c.642G>T p.S214= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV51648757, COSV51650140; called by muse, mutect2, varscan2
- TOX2 | c.1407G>T p.G469= (on ENST00000358131 / NM_001098798.2; = p.G445= on NM_032883.3) | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV57881827; called by muse, mutect2, varscan2
- TRPS1 | c.873G>T p.L291= (on ENST00000220888 / NM_001330599.2; = p.L304= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs372146914; called by muse, mutect2, varscan2
- UBE4B | c.3579A>T p.A1193= (on ENST00000343090 / NM_001105562.3; = p.A1064= on NM_006048.5) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53526875; called by mutect2, varscan2
- UNC5A | c.2445C>T p.G815= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV52836652; called by muse, mutect2
- UPF1 | c.2043G>C p.V681= (on ENST00000599848 / NM_001297549.2; = p.V670= on NM_002911.4) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV53193560; called by muse, mutect2, varscan2
- VDR | c.1254G>T p.V418= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57466710; called by muse, mutect2, varscan2
- VIT | c.699C>T p.T233= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV64894985; called by muse, mutect2, varscan2
- WASHC1 | c.1152G>A p.K384= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57924223; called by muse, mutect2, varscan2
- WDR81 | c.5796A>T p.S1932= (on ENST00000409644 / NM_001163809.2; = p.S881= on NM_152348.4) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV58478155; called by muse, mutect2, varscan2
- XYLT1 | c.1971C>T p.R657= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV99762793; called by muse, mutect2, varscan2
- ZNF135 | c.1446C>A p.T482= (on ENST00000313434 / NM_001289401.2; = p.T494= on NM_003436.4) | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV57879940; called by muse, mutect2, varscan2
- AL136982.4 | n.1447C>G | RNA (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-1del | 5'UTR (DEL) | VAF 57/189 reads (30%) | called by mutect2, pindel, varscan2
- H3-3B | chr17:75784731 G>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53139080; called by muse, mutect2
- H3-3B | chr17:75784733 C>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53139089; called by muse, mutect2
- LBHD1 | c.617-531G>A | Intron (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100649204; called by muse, mutect2, varscan2
- MIR516B1 | n.18C>T | RNA (SNP) | VAF 20/118 reads (17%) | catalogued as rs754712551; called by muse, mutect2
- MYRF | c.46+2647C>A | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99607541; called by muse, mutect2, varscan2
- SNORD116-18 | n.78G>T | RNA (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.-537del | 5'UTR (DEL) | VAF 18/50 reads (36%) | called by pindel, varscan2
- UCHL5 | chr1:193059961 C>T | 5'Flank (SNP) | VAF 5/50 reads (10%) | catalogued as rs772044717, COSV66477912; called by mutect2, varscan2
